Surgical pathology report (de-identified scan), TCGA case TCGA-BF-AAP6, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Cureline, specimen TCGA-BF-AAP6-01A (Primary Tumor).

Case #

Patient: **Age (years):** **Gender:** **Male**

Clinical diagnosis: Melanoma

Date of procurement:

Sample:

Gross description:

The material presented – skin flap from right leg

Microscopic description:

Skin and fat flap 15x8 cm with dark-brown mushroom formation of 4x3 cm wide
leg 2 cm thick mushroom shape epithelioid melanoma with ulceration, Breslow -
20 mm, Clark - IV. Stage III, T4. N2, M0

Final diagnosis: Epithelioid cell melanoma

ICD-O-3
Melanoma, epithelioid cell 8771/3
Site: Skin, @ leg C44.7
QJ 4/22/14

Confidential

Source: NCI Genomic Data Commons file f2b70878-08d0-4b0c-b01c-39f5f9cbca27 (TCGA-BF-AAP6.D3B99086-110C-4DE5-BBF7-65C4ABD29959.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).